Somatic mutation profile of tumor specimen MMRF_1496_1_BM_CD138pos (aliquot MMRF_1496_1_BM_CD138pos_T14_KBS5U_L05830) from MMRF case MMRF_1496, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.9 years (14,564 days).
Specimen MMRF_1496_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5daa2848-5528-40b2-b6b3-527d968ff7ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1496_3_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1496_3_PB_CD3pos_C5_KBS5U_L06506; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/773caf33-5d98-4262-be27-9bbe6e766dcb

The open-access MAF lists 48 somatic variants for this specimen: 14 protein-altering or splice-affecting, 11 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 15, Missense Mutation 12, Silent 11, Intron 3, 5'UTR 2, 5'Flank 2, Frame Shift Del 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 33/48 reads (69%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AADACL2 | c.366G>C p.Q122H | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100735732; called by muse, mutect2, varscan2
- ARFGEF1 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51610018; called by muse, mutect2, varscan2
- CLSTN3 | c.2336G>A p.R779Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs746709429, COSV56939319; called by mutect2, varscan2
- DHX57 | c.194G>C p.C65S | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); catalogued as rs1207075515; called by muse, mutect2
- OR5AS1 | c.618C>G p.I206M | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1244873387; called by muse, mutect2, varscan2
- RB1CC1 | c.3058del p.E1020Kfs*5 | Frame Shift Del (DEL) | VAF 69/320 reads (22%) | catalogued as COSV50265638; called by mutect2, pindel, varscan2
- SQSTM1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs118160361; called by muse, mutect2, varscan2
- ADCY2 | c.2670T>A p.F890L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD1 | c.8496T>A p.F2832L (on ENST00000520002; = p.F2831L on NM_033225.6) | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MCF2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MYBBP1A | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PNPT1 | c.89T>G p.L30R | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- STOX1 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 81/199 reads (41%) | called by muse, mutect2, varscan2
- ADGRD1 | c.1650C>T p.L550= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as rs1417936457, COSV99894512; called by muse, mutect2
- CCDC30 | c.1357C>T p.L453= (on ENST00000340612; = p.L410= on NM_001080850.3) | Silent (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- CRYBG1 | c.2271A>G p.E757= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as rs766180081; called by muse, mutect2
- LOXL4 | c.2223A>G p.A741= | Silent (SNP) | VAF 54/185 reads (29%) | called by muse, mutect2, varscan2
- MID1 | c.195C>G p.L65= | Silent (SNP) | VAF 79/138 reads (57%) | called by muse, mutect2, varscan2
- PDK2 | c.150C>T p.F50= | Silent (SNP) | VAF 18/405 reads (4%) | called by muse, mutect2
- PUM3 | c.360G>A p.L120= | Silent (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- SIX2 | c.771G>T p.V257= | Silent (SNP) | VAF 50/151 reads (33%) | called by muse, mutect2, varscan2
- SLC26A1 | c.1170C>T p.L390= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99925680; called by muse, mutect2, varscan2
- THRAP3 | c.636A>G p.Q212= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- TNRC18 | c.5127C>T p.F1709= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs760375574; called by muse, mutect2, varscan2
- APBA2 | c.*361C>T | 3'UTR (SNP) | VAF 66/204 reads (32%) | catalogued as rs930614687; called by muse, mutect2, varscan2
- ARHGAP36 | c.*433G>A | 3'UTR (SNP) | VAF 37/62 reads (60%) | catalogued as rs1474219883; called by muse, mutect2, varscan2
- BDP1 | c.*720C>T | 3'UTR (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- ELOVL6 | c.*3833C>G | 3'UTR (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- IGDCC3 | c.*526A>G | 3'UTR (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- LRRIQ3 | c.*510G>A | 3'UTR (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.*408G>A | 3'UTR (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- NLE1 | c.*489C>T | 3'UTR (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- NSUN2 | chr5:6633105 G>A | 5'Flank (SNP) | VAF 21/40 reads (53%) | catalogued as rs530758742; called by muse, mutect2, varscan2
- NSUN2 | chr5:6633106 G>A | 5'Flank (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- PGAM5 | c.719+694C>T | Intron (SNP) | VAF 24/187 reads (13%) | catalogued as COSV100452953; called by muse, mutect2, varscan2
- PIK3CB | c.*1461C>T | 3'UTR (SNP) | VAF 7/36 reads (19%) | catalogued as rs1268543208; called by muse, mutect2
- PIP4P2 | c.*1726C>T | 3'UTR (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- PPIL1 | c.*775G>A | 3'UTR (SNP) | VAF 54/151 reads (36%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.684T>G | RNA (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- RTL6 | c.*581T>C | 3'UTR (SNP) | VAF 7/204 reads (3%) | called by muse, mutect2
- SESN3 | c.*7688C>T | 3'UTR (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- SLC39A8 | c.-21C>T | 5'UTR (SNP) | VAF 17/55 reads (31%) | catalogued as rs1560576299; called by muse, mutect2, varscan2
- SYNRG | c.*988G>C | 3'UTR (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- TECR | c.16-19G>A | Intron (SNP) | VAF 25/112 reads (22%) | catalogued as rs1377984900; called by muse, mutect2, varscan2
- TSPAN9 | c.-17-165G>A | Intron (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- WRAP53 | c.-507G>C | 5'UTR (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- ZFP91 | c.*1405_*1410del | 3'UTR (DEL) | VAF 28/62 reads (45%) | called by mutect2, varscan2
